Gene-level copy-number profile of tumor specimen TCGA-2G-AAF0-01A from TCGA case TCGA-2G-AAF0, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 41.9 years (15,287 days).
Specimen TCGA-2G-AAF0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 98b6f067-4694-4d1c-a51a-143489e6226d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAF0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/b0daa789-c66b-49cd-88db-edab8d226d04

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 513; copy number 2: 877; copy number 3: 14,792; copy number 4: 13,419; copy number 5: 15,909; copy number 6: 4,573; copy number 7: 3,372; copy number 8: 3,273; copy number 9: 1,541; copy number 10: 551; copy number 13: 67; copy number 14: 6; copy number 16: 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr5:710,355–850,986, 4 genes (within-gene range 0–2): ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 75 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,396,754–121,580,524, 6 genes, copy number 14 (within-gene range 3–14): LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr8:95,986,108–96,336,995, 10 genes, copy number 13: AC012339.1, GAPDHP30, AC007992.1, AP003465.2, GDF6, UQCRB, AP003465.1, MTERF3, PTDSS1, Y_RNA.
- chr12:93,894,965–96,269,824, 59 genes, copy number 13–16: AC012464.1, AC012464.3, RN7SKP263, AC123567.1, PLXNC1, AC123567.2, AC073655.3, AC073655.1, AC073655.2, CEP83, RN7SL330P, RBMS2P1, CEP83-DT, AC023161.1, RN7SL483P, NSA2P2, SUCLG2P2, MIR5700, TMCC3, MIR7844, LSM3P2, KRT19P2, MIR492, NDUFA12, NR2C1, FGD6, AC126615.2, AC126615.1, VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685, AC084879.1, AC084879.2, RNU6-735P, AC018475.1, METAP2, USP44, PGAM1P5, Y_RNA, NTN4, AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2, AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P, ELK3, AC008149.1, AC008149.2.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
